CCDI case PBCFVA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/893813a4-4a0c-48d7-a72d-a865cdacb1e9

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 12.2 years (4,472 days).

Biospecimens (2 samples)
- Sample 0DRELD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRELF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
